Gene-level copy-number profile of tumor specimen ALCH-B1J9-TTP1-A from ALCHEMIST case ALCH-B1J9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.6 years (27,613 days).
Specimen ALCH-B1J9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f038592f-f235-4925-9504-9c620b146fbc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1J9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/6c10ac36-6522-4b41-a32b-6522683ee2ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 4,095; copy number 2: 53,735; copy number 3: 381; copy number 4: 31; copy number 5: 7; copy number 6: 1; copy number 7: 2; copy number 8: 6; copy number 10: 1; copy number 11: 1; copy number 14: 1; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,607,715–46,616,884, 1 gene (within-gene range 0–2): MOB3C.
- chr1:54,416,256–54,420,860, 1 gene: AL035415.1.
- chr1:114,089,291–114,153,880, 1 gene: SYT6.
- chr2:8,600,892–8,622,942, 2 genes (within-gene range 0–2): AC011747.1, SNRPEP5.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr2:219,195,237–219,229,717, 5 genes: ZFAND2B, AC068946.3, ABCB6, AC068946.2, ATG9A.
- chr5:100,375,700–100,389,938, 2 genes: AC113385.3, AC113385.2.
- chr6:42,696,598–42,727,700, 2 genes: PRPH2, ATP6V0CP3.
- chr7:66,070,904–66,094,697, 2 genes (within-gene range 0–2): AC068533.1, ASL.
- chr7:66,493,607–66,545,066, 3 genes (within-gene range 0–2): GS1-124K5.4, AC008267.1, AC008267.3.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr9:60,914,407–61,453,030, 12 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr10:73,813,518–73,814,737, 1 gene (within-gene range 0–1): AC022400.1.
- chr10:133,257,144–133,257,551, 1 gene: AL592071.1.
- chr11:130,404,923–130,428,609, 1 gene: ADAMTS8.
- chr14:99,500,190–99,604,207, 1 gene (within-gene range 0–2): CCDC85C.
- chr14:99,583,017–99,625,740, 2 genes: Y_RNA, AL160313.1.
- chr14:105,489,855–105,499,575, 1 gene (within-gene range 0–5): TEDC1.
- chr15:25,180,497–25,232,468, 29 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34.
- chr15:41,828,095–41,899,528, 6 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:41,908,204–41,908,714, 1 gene (within-gene range 0–2): AC039056.2.
- chr15:45,129,933–45,201,175, 6 genes (within-gene range 0–2): DUOX1, AC051619.5, SHF, AC051619.3, AC051619.6, AC051619.7.
- chr15:74,812,716–74,831,795, 2 genes (within-gene range 0–2): LMAN1L, AC091230.1.
- chr15:80,946,289–80,989,828, 1 gene (within-gene range 0–2): MESD.
- chr15:85,744,109–85,756,237, 3 genes (within-gene range 0–3): AC021739.2, AC021739.4, LINC02883.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–2): MIR1276, AC021739.1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:2,177,180–2,214,840, 5 genes (within-gene range 0–3): CASKIN1, MLST8, BRICD5, PGP, AC009065.7.
- chr16:2,239,402–2,252,300, 2 genes: ECI1, AC009065.8.
- chr16:19,856,691–19,886,167, 1 gene (within-gene range 0–2): GPRC5B.
- chr16:32,051,825–32,066,358, 3 genes (within-gene range 0–1): AC142381.1, IGHV1OR16-3, IGHV3OR16-9.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:18,968,789–19,004,764, 2 genes (within-gene range 0–1): FAM83G, AC090286.4.
- chr17:29,073,521–29,078,857, 1 gene (within-gene range 0–2): TIAF1.
- chr17:41,609,778–41,615,899, 1 gene: KRT16.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr17:57,955,965–57,956,143, 1 gene: AC015813.4.
- chr18:79,515,798–79,516,057, 1 gene (within-gene range 0–2): AC018445.2.
- chr19:17,292,131–17,323,298, 4 genes (within-gene range 0–2): ABHD8, MRPL34, AC010463.3, DDA1.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–4): BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,598,012–1,600,135, 1 gene, copy number 14: FNDC10.
- chr1:23,281,307–23,287,488, 1 gene, copy number 5: LINC01355.
- chr8:144,051,266–144,063,965, 2 genes, copy number 7 (within-gene range 2–7): OPLAH, MIR6846.
- chr9:134,849,298–134,850,641, 6 genes, copy number 8: MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E.
- chr12:132,144,457–132,152,473, 1 gene, copy number 6: NOC4L.
- chr14:105,472,962–105,492,267, 3 genes, copy number 5 (within-gene range 0–5): CRIP2, CRIP1, AL928654.3.
- chr21:43,446,601–43,479,534, 2 genes, copy number 10–30 (within-gene range 1–30): LINC00319, LINC00313.
- chr22:21,354,563–21,358,067, 1 gene, copy number 11: LINC01651.

Autosomal genes at a single copy (total copy number 1): 3,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
